Somatic mutation profile of tumor specimen TCGA-IM-A41Y-01A (aliquot TCGA-IM-A41Y-01A-11D-A23U-08) from TCGA case TCGA-IM-A41Y, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nonencapsulated sclerosing carcinoma; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.0 years (15,694 days).
Specimen TCGA-IM-A41Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5248ba6-91b5-41c0-a05c-2ffeac00a0e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A41Y-10A (Blood Derived Normal), aliquot TCGA-IM-A41Y-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19baaead-5a10-4447-bad9-04ffdf3466c4

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Splice Region 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CATSPER4 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100128585; called by muse, mutect2
- DYNC2I2 | c.981G>A p.K327= | Splice Region (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100824137; called by muse, mutect2, varscan2
- HELZ2 | c.1626C>G p.I542M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100915744; called by muse, mutect2, varscan2
- MKLN1 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100760068; called by muse, mutect2, varscan2
- NETO1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as rs1269426198, COSV55002393; called by muse, mutect2
- PSMC5 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.32); catalogued as COSV99856708; called by muse, mutect2, varscan2
- SPTBN5 | c.3214_3215insT p.P1072Lfs*29 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as COSV100312437; called by mutect2, pindel
- TEX15 | c.1549G>C p.D517H (on ENST00000256246; = p.D900H on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV99822377; called by muse, mutect2, varscan2
- TJP3 | c.2394C>G p.S798R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53663314, COSV99516566; called by muse, mutect2, varscan2
- TNC | c.5326C>G p.L1776V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV100406470, COSV60785465; called by muse, mutect2, varscan2
- TSGA10 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV100747737, COSV61825234; called by muse, mutect2, varscan2
- ZBTB43 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as COSV100991494; called by muse, mutect2, varscan2
- ZNF236 | c.4922C>G p.S1641C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99471511; called by muse, mutect2, varscan2
- BOD1L1 | c.7515G>A p.L2505= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99240614; called by muse, mutect2
- DDX54 | c.1608G>A p.E536= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100014283; called by muse, mutect2, varscan2
- HLA-C | c.30C>A p.L10= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100881179; called by muse, mutect2, varscan2
- OR5M3 | c.738C>T p.V246= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100392726; called by muse, mutect2
- SLC30A5 | c.1671A>G p.S557= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs144055477; called by muse, mutect2, varscan2
- TRIP13 | c.882G>A p.V294= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV99386603; called by muse, mutect2
- HTR2C | c.-80+38827G>C | Intron (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
